Surgical pathology report (de-identified scan), TCGA case TCGA-QU-A6IM, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Harvard Beth Israel, specimen TCGA-QU-A6IM-01A (Primary Tumor).

[page 1 of 3]
Pathology Examination

Name	Birthdate	Age	Sex	Pathology #
[REDACTED]	[REDACTED]		Male	

Report to:
Gross Description by.

SPECIMEN SUBMITTED: PROSTATE, RT & LT OBTURATOR NODES.

Procedure date Tissue received Report Date Diagnosed by

Previous biopsies: PROSTATE BX'S.
LT LEG
PUNCH EXCISION LT LEG
GI BX

(and more)

Diagnosis:

1. Right obturator lymph node: One lymph node, no malignancy identified.
2. Left obturator lymph node: One lymph node, no malignancy identified.
3. Prostate: Adenocarcinoma, see synoptic report.

Q&F ICD-O-3
Adenocarcinoma, acinar
8140/3
path
Adenocarcinoma NOS
8140/3
Site Prostate NOS
C61.9
JW 6/17/13

Prostatic Carcinoma Synopsis

Type of specimen: Prostate and seminal vesicles.

Procedure: Radical prostatectomy.

Tumor type: Adenocarcinoma.

Tumor histologic grade (Gleason's)

Primary pattern: 3.
Secondary pattern: 4.
Score: 7.

[page 2 of 3]
Tumor amount (radical prostatectomies)

	Positive slides	Total
Right	0	3
Right Apex	0	2
Left	2	4
Left apex	1	2

Vascular/lymphatic invasion: Absent.

Perineural extension: Present, within prostate.

Surgical margins

Inked capsular/soft tissue resection margins: Free.

Shaved bladder margin: Free.

Inked apex margin: Free.

Seminal vesicles

Not involved by tumor: .

Lymph nodes

	Total	# positive	Size of tumor metastasis
Right pelvic	1	0	
Left pelvic	1	0	

Clinical: Adenocarcinoma of the prostate

Gross:

The specimen is received fresh in three parts, all labeled [REDACTED]

Part 1 is additionally labeled "right obturator lymph node" and consists of a 5 x 2 x 0.7 cm fibrofatty tissue fragment which is dissected to reveal a single 1.8 x 1 x 0.4 cm possible lymph node. The lymph node is serially sectioned and entirely submitted in A-B.

Part 2 is additionally labeled "left obturator lymph node" and consists of a 5 x 3 x 1 cm fibrofatty tissue fragment. The specimen is dissected to reveal a 1 x 0.6 x 0.2 cm possible lymph node which is serially sectioned and entirely submitted in C.

Part 3 is additionally labeled "prostate, 1 chromic stitch at right seminal vesicle" and consists of a 43 gram, 4.5 x 4 x 3.5 cm prostatectomy specimen. The right vas deferens measures 1.7 cm in length by 0.3 cm in diameter and the right seminal vesicle measures 2.5 x 1.3 x 1 cm. The left vas deferens measures 2 cm in length by 0.3 cm in diameter and the left seminal vesicle measures 2.6 x 1.4 x 1.2 cm. The right half of the specimen is inked in black and the left half is inked in blue. The specimen is serially sectioned to reveal an approximately 0.3 cm diameter firm area in the left posterior apex, a 0.5 cm firm area in the right anterior apex, a 0.9 cm nodular firm area in the left anterior mid portion of the prostate, and a 0.4 cm diameter firm area in the right and left posterior mid prostate and left posterior base. The specimen is represented as follows:

[page 3 of 3]
D = shaved base margin
E-H = coned apex margin
I = right vas deferens resection margin and right seminal vesicle.
J = left vas deferens margin and left seminal vesical
K = right anterior apex firm area
L = left posterior apex firm area
M = left anterior mid nodular area
N = left posterior mid firm area
O = right posterior mid firm area
P = left posterior base firm area
Q = unremarkable right posterior base

By his/her signature above, the senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimens(s) and rendered or confirmed the diagnosis(es) related thereto.

Immunohistochemistry test(s), if applicable, were developed and their performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA - 88) as qualified to perform high complexity clinical laboratory testing.

Per TSS, patient received NO systemic chemotherapy for their prior Hodgkin Lymphoma. BCR

Criteria:	6/12/13	Yes	No
Prior Malignancy History	Hodgkin Lymphoma	✓	

Source: NCI Genomic Data Commons file 92a8b665-eec8-4b14-9fbd-b35c8856b38f (TCGA-QU-A6IM.6999B5F3-AC5C-4447-9590-548F103039C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).